Somatic mutation profile of tumor specimen ALCH-B1OJ-TTP1-A (aliquot ALCH-B1OJ-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1OJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,866 days).
Specimen ALCH-B1OJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92daaa36-7d12-4183-8593-808ce027eaa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OJ-NB1-A (Blood Derived Normal), aliquot ALCH-B1OJ-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aacb9213-e250-4379-ab70-6b84d1887674

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Frame Shift Del 5, 5'UTR 3, RNA 2, 3'UTR 2, Intron 2, Splice Region 1, Splice Site 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 410/1195 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 97/560 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APP | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 109/766 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.928); catalogued as rs201885206; called by muse, mutect2, varscan2
- ATM | c.7829G>A p.R2610K | Missense Mutation (SNP) | VAF 44/594 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as CD982465; called by muse, mutect2
- BIVM-ERCC5 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 66/684 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57278510; called by muse, mutect2
- C16orf96 | c.2947G>A p.A983T | Missense Mutation (SNP) | VAF 59/530 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1370304847; called by muse, mutect2, varscan2
- C20orf96 | c.803A>C p.K268T (on ENST00000360321 / NM_153269.3; = p.K267T on NM_080571.1) | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs747835513, COSV64404814; called by muse, mutect2, varscan2
- COL24A1 | c.4706C>T p.P1569L | Missense Mutation (SNP) | VAF 69/607 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs773426204; called by muse, mutect2, varscan2
- DNAH7 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100413748, COSV56765389; called by muse, mutect2, varscan2
- GON4L | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 148/802 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV55194613; called by muse, mutect2, varscan2
- MAEL | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 55/486 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.153); catalogued as COSV63303955; called by muse, mutect2, varscan2
- MKI67 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 30/567 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.099); catalogued as rs374315037; called by muse, mutect2
- P2RX5 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 47/580 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs369632150; called by muse, mutect2
- PDE1C | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 97/739 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs868133283, COSV58509320; called by muse, mutect2, varscan2
- PRND | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 63/690 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs551957084, COSV59896228; called by muse, mutect2
- RGS2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 150/849 reads (18%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs142499684; called by muse, mutect2, varscan2
- SLC29A4 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 92/440 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267228610; called by muse, mutect2, varscan2
- TTLL7 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 109/554 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs756033521; called by muse, mutect2, varscan2
- ADGRB3 | c.4244G>T p.R1415I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- CAST | c.670-2A>G p.X224_splice (on ENST00000341926; = p.X307_splice on NM_001750.7 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 104/441 reads (24%) | called by muse, mutect2, varscan2
- CATSPER3 | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 132/1053 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CD1E | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DLX5 | c.866_*16del | Nonstop Mutation (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- EIF2S2 | c.951_967del p.F318Qfs*10 | Frame Shift Del (DEL) | VAF 24/303 reads (8%) | called by mutect2, pindel
- EML2 | c.711del p.S238Afs*2 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | called by mutect2, varscan2
- EML2 | c.710del p.G237Afs*3 | Frame Shift Del (DEL) | VAF 17/211 reads (8%) | called by mutect2*, pindel
- EYS | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 45/267 reads (17%) | called by muse, varscan2
- FSIP2 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ISM1 | c.560G>T p.S187I | Missense Mutation (SNP) | VAF 26/620 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2
- MDM1 | c.1271A>G p.N424S | Missense Mutation (SNP) | VAF 41/507 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2
- MTMR11 | c.772-6G>A | Splice Region (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- PCNT | c.8698A>G p.S2900G | Missense Mutation (SNP) | VAF 23/616 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- PLA2R1 | c.3285_3288del p.C1096Kfs*11 | Frame Shift Del (DEL) | VAF 44/220 reads (20%) | called by pindel, varscan2
- POGZ | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 56/553 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPEL1 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 72/857 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- SARDH | c.1534C>T p.H512Y | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- SLC44A4 | c.2078A>T p.K693M | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SPTBN4 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TRPC5 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2
- UNC13B | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 64/916 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.013); called by muse, mutect2
- UPK3A | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); called by muse, mutect2
- VEGFD | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF502 | c.103del p.I35Lfs*6 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | called by mutect2, pindel
- ZSCAN9 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); called by muse, varscan2
- ABCA9 | c.2679G>A p.P893= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as rs140649599; called by muse, mutect2, varscan2
- ACTR3C | c.189G>A p.L63= | Silent (SNP) | VAF 71/367 reads (19%) | called by muse, mutect2, varscan2
- C1orf198 | c.570C>T p.F190= | Silent (SNP) | VAF 73/367 reads (20%) | catalogued as COSV64176080; called by muse, mutect2, varscan2
- DGKG | c.1152C>T p.D384= | Silent (SNP) | VAF 35/685 reads (5%) | catalogued as rs770406720, COSV53974153; called by muse, mutect2
- FSIP2 | c.15297C>A p.I5099= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- LSMEM1 | c.184C>T p.L62= | Silent (SNP) | VAF 66/671 reads (10%) | catalogued as COSV100456303, COSV57196528; called by muse, mutect2, varscan2
- MAST2 | c.4332G>A p.R1444= | Silent (SNP) | VAF 106/543 reads (20%) | called by muse, mutect2, varscan2
- NLE1 | c.213C>T p.S71= | Silent (SNP) | VAF 91/606 reads (15%) | called by muse, mutect2, varscan2
- NLRP10 | c.681C>T p.C227= | Silent (SNP) | VAF 28/332 reads (8%) | catalogued as rs564306322, COSV60778788, COSV60781680; called by muse, mutect2
- PPP1R3A | c.6G>A p.E2= | Silent (SNP) | VAF 45/394 reads (11%) | called by muse, mutect2, varscan2
- PROX1 | c.1260C>T p.P420= | Silent (SNP) | VAF 28/350 reads (8%) | catalogued as COSV54778915; called by muse, mutect2
- SHROOM2 | c.1362C>T p.N454= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs375147235; called by muse, mutect2
- BTD | c.-333G>A | 5'UTR (SNP) | VAF 71/419 reads (17%) | catalogued as rs776094195; called by muse, mutect2, varscan2
- CEP95 | c.2070+61_2070+68del | Intron (DEL) | VAF 40/266 reads (15%) | called by mutect2, pindel
- CTSH | c.493-24_493-17del | Intron (DEL) | VAF 36/384 reads (9%) | called by mutect2, pindel
- ENHO | c.*137A>G | 3'UTR (SNP) | VAF 52/462 reads (11%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.633A>T | RNA (SNP) | VAF 23/588 reads (4%) | called by muse, mutect2
- MIDEAS | c.*399G>T | 3'UTR (SNP) | VAF 20/168 reads (12%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.32C>G | RNA (SNP) | VAF 40/732 reads (5%) | called by muse, mutect2
- NBAS | c.-24C>T | 5'UTR (SNP) | VAF 40/558 reads (7%) | called by muse, mutect2
- TIMM29 | c.-12A>C | 5'UTR (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
